Somatic mutation profile of tumor specimen 0DN1D7 from CCDI case PBCAMB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.4 years (5,641 days).
Specimen 0DN1D7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c365bd2-53bf-4c14-82ea-f39ea4a0a6d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DN1AZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab57a67b-a2b2-4211-88a5-248547de155a

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 2, Nonsense Mutation 2, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ZEB2 | c.1102C>T p.Q368* | Nonsense Mutation (SNP) | VAF 171/1149 reads (15%) | catalogued as rs886041338, CM072127, COSV57952226; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ZNRF3 | c.1633G>A p.D545N (on ENST00000544604 / NM_001206998.2; = p.D445N on NM_032173.3) | Missense Mutation (SNP) | VAF 77/433 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1470548694, COSV60434168; called by muse, mutect2, varscan2
- ACACB | c.4111G>A p.A1371T | Missense Mutation (SNP) | VAF 33/883 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.868); called by muse, mutect2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 54/1572 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- SLITRK4 | c.1714A>T p.K572* | Nonsense Mutation (SNP) | VAF 52/1124 reads (5%) | called by muse, mutect2
- TEX15 | c.1096A>C p.K366Q (on ENST00000256246; = p.K749Q on NM_001350162.2) | Missense Mutation (SNP) | VAF 199/904 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- THADA | c.636G>T p.Q212H | Missense Mutation (SNP) | VAF 43/1438 reads (3%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); called by muse, mutect2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 55/1288 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- LRRC47 | c.1740T>C p.T580= | Silent (SNP) | VAF 28/486 reads (6%) | catalogued as rs1375574782, COSV65562054; called by muse, mutect2
- PARP4 | c.975C>T p.Y325= | Silent (SNP) | VAF 258/826 reads (31%) | called by muse, mutect2, varscan2
- LRRC7 | c.1421-34A>T | Intron (SNP) | VAF 35/447 reads (8%) | catalogued as rs1415560984; called by mutect2, varscan2
- THSD4 | c.-42C>T | 5'UTR (SNP) | VAF 68/484 reads (14%) | catalogued as rs374127318; called by muse, mutect2, varscan2
